Somatic mutation profile of tumor specimen 50997c44-1c8b-4d34-b535-4a6cc2 (aliquot 50997c44-1c8b-4d34-b535-4a6cc2_D6) from CPTAC case 04OV040, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 50997c44-1c8b-4d34-b535-4a6cc2: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05f867c7-1bad-4fa0-81a6-0981682e316e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen fbe99290-8eba-45ae-ad79-38442b (Blood Derived Normal), aliquot fbe99290-8eba-45ae-ad79-38442b_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b065fc9-be3b-4611-82d8-830621d84d28

The open-access MAF lists 125 somatic variants for this specimen: 73 protein-altering or splice-affecting, 29 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 29, Intron 14, 3'UTR 3, RNA 2, Splice Site 2, Frame Shift Del 2, 5'Flank 2, Translation Start Site 1, Splice Region 1, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACO2 | c.1501A>G p.I501V | Missense Mutation (SNP) | VAF 152/214 reads (71%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); catalogued as rs774584067; called by muse, mutect2, varscan2
- APOB | c.4083T>A p.N1361K | Missense Mutation (SNP) | VAF 58/356 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV51937939, COSV51944923; called by muse, mutect2, varscan2
- CCNB1 | c.1084-1G>T p.X362_splice | Splice Site (SNP) | VAF 22/63 reads (35%) | catalogued as COSV56511090; called by muse, mutect2, varscan2
- CDK17 | c.1029G>C p.K343N | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1343777100, COSV54130716; called by muse, mutect2, varscan2
- DNAH17 | c.2741C>T p.P914L | Missense Mutation (SNP) | VAF 46/254 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs370734377, COSV101101682, COSV67761060; called by muse, mutect2, varscan2
- EHMT2 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 29/287 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as rs763118108; called by muse, mutect2, varscan2
- F5 | c.3610C>T p.L1204F | Missense Mutation (SNP) | VAF 61/394 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1360635181; called by muse, mutect2, varscan2
- FER1L6 | c.2885C>G p.S962C | Missense Mutation (SNP) | VAF 18/209 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV67552959; called by muse, mutect2
- IRF4 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 48/320 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); catalogued as rs1400777715, COSV101110790; called by muse, mutect2, varscan2
- KCNA1 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.005); catalogued as COSV101230095; called by muse, mutect2, varscan2
- KIRREL3 | c.742+1G>C p.X248_splice | Splice Site (SNP) | VAF 22/82 reads (27%) | catalogued as COSV73109852; called by muse, mutect2, varscan2
- OR52E6 | c.501G>T p.R167S | Missense Mutation (SNP) | VAF 49/250 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1183253130, COSV61432564; called by muse, mutect2, varscan2
- PROKR2 | c.472G>T p.V158F | Missense Mutation (SNP) | VAF 27/316 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs368732206, CM1312721; called by muse, mutect2
- RDH16 | c.923G>A p.W308* | Nonsense Mutation (SNP) | VAF 46/385 reads (12%) | catalogued as rs765789629; called by muse, varscan2
- RTEL1 | c.2870G>A p.R957Q | Missense Mutation (SNP) | VAF 91/290 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs753270617; called by mutect2, varscan2
- SCN3A | c.3698G>A p.R1233Q | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1442271712, COSV51827749; called by muse, mutect2, varscan2
- SGO2 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.164); catalogued as rs942216451; called by muse, mutect2, varscan2
- SIGLEC6 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.72); catalogued as rs752121580, COSV58431606; called by muse, mutect2, varscan2
- SLC26A4 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs779745819, CM1111378, COSV55916347; called by muse, mutect2, varscan2
- TMEM161A | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 46/373 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs773542916, COSV50777931, COSV99365340; called by muse, mutect2, varscan2
- TNFRSF1A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 40/326 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.028); catalogued as rs116336305; called by mutect2, varscan2
- ZBTB17 | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV65269584; called by muse, mutect2
- ABHD16A | c.135T>A p.D45E | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2
- AGBL1 | c.361T>A p.C121S | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- AMPD1 | c.925A>G p.M309V | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ANKRD33B | c.377T>C p.I126T | Missense Mutation (SNP) | VAF 57/273 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ANO8 | c.2151G>C p.W717C | Missense Mutation (SNP) | VAF 68/284 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ANTKMT | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 121/571 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ASCC3 | c.4576A>T p.I1526F | Missense Mutation (SNP) | VAF 48/332 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BRD1 | c.32C>G p.S11C | Missense Mutation (SNP) | VAF 7/186 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2
- C12orf40 | c.1523A>T p.Q508L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- C9orf135 | c.518G>C p.C173S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0.007); called by mutect2, varscan2
- CACNA1S | c.1368G>T p.Q456H | Missense Mutation (SNP) | VAF 110/708 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC38 | c.1137T>A p.D379E | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CCDC50 | c.795G>C p.W265C | Missense Mutation (SNP) | VAF 37/291 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CNTROB | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- COL15A1 | c.1244A>T p.E415V | Missense Mutation (SNP) | VAF 84/263 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CREBBP | c.2795C>G p.T932S | Missense Mutation (SNP) | VAF 57/290 reads (20%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CYP2C18 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- DNAH3 | c.8742G>C p.K2914N | Missense Mutation (SNP) | VAF 113/262 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- EEF1AKMT3 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FAM168B | c.505C>A p.P169T | Missense Mutation (SNP) | VAF 40/238 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- FRY | c.2959G>T p.V987F | Missense Mutation (SNP) | VAF 93/495 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAS2L3 | c.676T>G p.C226G | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GJC1 | c.847A>G p.T283A | Missense Mutation (SNP) | VAF 47/288 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRM3 | c.1337del p.P446Qfs*8 | Frame Shift Del (DEL) | VAF 20/119 reads (17%) | called by mutect2, pindel, varscan2
- IL23R | c.14C>A p.T5N | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- LCE2B | c.302G>A p.G101D | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- NLRP5 | c.2797del p.C933Vfs*21 | Frame Shift Del (DEL) | VAF 67/127 reads (53%) | called by mutect2, varscan2
- NR0B2 | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NUTM2B | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 112/1266 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.053); called by muse, mutect2
- OXR1 | c.904A>G p.K302E (on ENST00000442977 / NM_001198532.1; = p.K301E on NM_018002.3) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.18); called by muse, mutect2
- PRMT9 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.139); called by mutect2, varscan2
- PTPN4 | c.574C>A p.H192N | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- RAG2 | c.1140C>G p.D380E | Missense Mutation (SNP) | VAF 53/376 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- SGSM1 | c.72G>C p.Q24H | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SIGLEC14 | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2
- SLC19A2 | c.61C>G p.R21G | Missense Mutation (SNP) | VAF 14/352 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- SLC1A7 | c.474G>A p.Q158= | Splice Region (SNP) | VAF 63/212 reads (30%) | called by muse, mutect2, varscan2
- SNCAIP | c.2504A>T p.E835V | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- TENT5B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/39 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TMC7 | c.2027G>A p.C676Y | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- TOR3A | c.357C>G p.I119M | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- TRHDE | c.1538T>A p.L513Q | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TXNDC11 | c.1045G>C p.E349Q (on ENST00000356957 / NM_001303447.2; = p.E322Q on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/514 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.333); called by muse, mutect2
- UBA2 | c.324G>C p.Q108H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- VIP | c.117C>G p.D39E | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDFY4 | c.5505G>T p.K1835N | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- WNT9B | c.428G>T p.C143F | Missense Mutation (SNP) | VAF 62/265 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- YBX1 | c.373G>C p.V125L | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by mutect2, varscan2
- ZNF430 | c.1565T>G p.F522C | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF436 | c.1397G>C p.R466T | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); called by muse, mutect2
- ZNF609 | c.1668dup p.G557Rfs*20 | Frame Shift Ins (INS) | VAF 19/188 reads (10%) | called by mutect2, pindel, varscan2
- ABCB8 | c.447G>A p.G149= (on ENST00000297504 / NM_001282291.2; = p.G132= on NM_007188.5) | Silent (SNP) | VAF 58/281 reads (21%) | called by muse, mutect2, varscan2
- ABCC3 | c.2493G>A p.E831= | Silent (SNP) | VAF 66/274 reads (24%) | catalogued as rs746296104; called by muse, mutect2, varscan2
- ACHE | c.207G>A p.A69= | Silent (SNP) | VAF 28/244 reads (11%) | catalogued as rs376602129; called by muse, mutect2, varscan2
- ADAM23 | c.2265C>A p.A755= | Silent (SNP) | VAF 17/96 reads (18%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.2958C>T p.Y986= | Silent (SNP) | VAF 38/318 reads (12%) | catalogued as rs142964907; called by muse, mutect2, varscan2
- CASR | c.1485G>A p.E495= (on ENST00000490131; = p.E572= on NM_000388.4) | Silent (SNP) | VAF 54/516 reads (10%) | catalogued as rs946945741, COSV99948861; called by muse, mutect2, varscan2
- CCNE1 | c.303A>G p.R101= | Silent (SNP) | VAF 16/146 reads (11%) | called by muse, mutect2, varscan2
- CDHR4 | c.1371G>A p.A457= | Silent (SNP) | VAF 59/498 reads (12%) | catalogued as rs535266119, COSV58526451; called by muse, mutect2, varscan2
- CDKN1B | c.15A>G p.R5= | Silent (SNP) | VAF 41/333 reads (12%) | called by muse, mutect2, varscan2
- CLCNKA | c.1809C>G p.L603= | Silent (SNP) | VAF 52/357 reads (15%) | catalogued as COSV100510319; called by muse, mutect2, varscan2
- COL4A3 | c.3228G>A p.P1076= | Silent (SNP) | VAF 30/202 reads (15%) | catalogued as rs200125890; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- DNAH1 | c.9714C>T p.S3238= | Silent (SNP) | VAF 91/316 reads (29%) | catalogued as rs1207313154; called by muse, mutect2, varscan2
- DNAH7 | c.4725C>T p.D1575= | Silent (SNP) | VAF 10/125 reads (8%) | called by muse, mutect2
- GNAS | c.1389C>T p.A463= | Silent (SNP) | VAF 109/224 reads (49%) | catalogued as COSV100007445; called by muse, mutect2, varscan2
- GPR78 | c.1044C>T p.N348= | Silent (SNP) | VAF 63/369 reads (17%) | catalogued as rs372186961; called by muse, mutect2, varscan2
- HSD3B2 | c.99C>T p.A33= | Silent (SNP) | VAF 71/416 reads (17%) | catalogued as rs1360211950, COSV101027544, COSV65593579; called by muse, mutect2, varscan2
- KALRN | c.6450C>T p.F2150= (on ENST00000360013 / NM_001024660.4; = p.F453= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/297 reads (8%) | catalogued as rs761915647, COSV52253904; called by muse, mutect2
- KHDC3L | c.24G>C p.P8= | Silent (SNP) | VAF 57/335 reads (17%) | called by muse, mutect2, varscan2
- KRT85 | c.102C>T p.I34= | Silent (SNP) | VAF 16/324 reads (5%) | catalogued as rs1299697011, COSV99225167; called by muse, mutect2
- LKAAEAR1 | c.327G>A p.R109= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as rs1367711843; called by muse, mutect2, varscan2
- MAPK12 | c.228C>G p.R76= | Silent (SNP) | VAF 19/120 reads (16%) | catalogued as rs1157614415; called by muse, mutect2, varscan2
- MISP3 | c.21G>A p.G7= | Silent (SNP) | VAF 12/248 reads (5%) | called by muse, mutect2
- MYH6 | c.2022C>T p.C674= | Silent (SNP) | VAF 34/783 reads (4%) | called by muse, mutect2
- OR8B2 | c.495A>G p.R165= | Silent (SNP) | VAF 46/154 reads (30%) | called by muse, mutect2, varscan2
- PPARGC1A | c.1380C>T p.A460= | Silent (SNP) | VAF 45/245 reads (18%) | catalogued as rs777545886, COSV99337579; called by muse, mutect2, varscan2
- PUM1 | c.315T>C p.N105= | Silent (SNP) | VAF 16/86 reads (19%) | called by muse, mutect2, varscan2
- SAP18 | c.66C>T p.R22= (on ENST00000607003; = p.R41= on NM_005870.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/121 reads (26%) | called by muse, mutect2, varscan2
- SPATA13 | c.600C>T p.F200= | Silent (SNP) | VAF 73/85 reads (86%) | catalogued as rs756923988; called by muse, mutect2, varscan2
- TENM2 | c.4146G>A p.Q1382= (on ENST00000518659 / NM_001122679.2; = p.Q1143= on NM_001080428.3) | Silent (SNP) | VAF 12/376 reads (3%) | catalogued as COSV69125197; called by muse, mutect2
- AC116655.1 | n.19G>T | RNA (SNP) | VAF 45/326 reads (14%) | called by muse, mutect2, varscan2
- CCDC97 | c.-4C>T | 5'UTR (SNP) | VAF 11/101 reads (11%) | called by muse, mutect2, varscan2
- CHN1 | c.627+554del | Intron (DEL) | VAF 19/95 reads (20%) | called by mutect2, pindel, varscan2
- DOCK6 | c.2718+984G>A | Intron (SNP) | VAF 36/538 reads (7%) | catalogued as rs1315199842; called by muse, mutect2
- FAM86C1P | n.183-16C>T | Intron (SNP) | VAF 58/133 reads (44%) | catalogued as rs751338086; called by muse, mutect2, varscan2
- FMO6P | n.510G>T | RNA (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- JPT2 | c.*321G>T | 3'UTR (SNP) | VAF 33/206 reads (16%) | called by muse, varscan2
- KALRN | c.5176+21776G>T | Intron (SNP) | VAF 27/213 reads (13%) | called by muse, mutect2, varscan2
- KYNU | c.374-7616C>G | Intron (SNP) | VAF 6/95 reads (6%) | called by muse, mutect2
- NAV3 | c.2024-12911G>A | Intron (SNP) | VAF 41/308 reads (13%) | catalogued as rs1350071736; called by muse, mutect2, varscan2
- NDUFA11 | c.97+2253C>A | Intron (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- NOP53 | c.1374-10C>G | Intron (SNP) | VAF 69/378 reads (18%) | called by muse, mutect2, varscan2
- NTRK3 | c.1586-38600G>A | Intron (SNP) | VAF 31/199 reads (16%) | catalogued as rs752063522; called by muse, mutect2, varscan2
- OPRM1 | c.1164+1952G>T | Intron (SNP) | VAF 20/210 reads (10%) | catalogued as rs1360084253; called by muse, mutect2
- PCGF2 | chr17:38749751 C>T | 5'Flank (SNP) | VAF 9/157 reads (6%) | called by muse, mutect2
- REXO1L1P | chr8:85655113 C>G | 3'Flank (SNP) | VAF 249/1581 reads (16%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159211 G>A | 5'Flank (SNP) | VAF 65/154 reads (42%) | catalogued as rs1436250768; called by muse, mutect2, varscan2
- SGSM2 | c.*810G>A | 3'UTR (SNP) | VAF 36/255 reads (14%) | catalogued as rs767324324; called by muse, varscan2
- SLC43A2 | c.1217+184T>A | Intron (SNP) | VAF 75/173 reads (43%) | called by muse, mutect2, varscan2
- TAC4 | c.123+1684T>C | Intron (SNP) | VAF 23/36 reads (64%) | catalogued as rs1246263251; called by muse, mutect2, varscan2
- TBX22 | c.356+9C>A | Intron (SNP) | VAF 82/253 reads (32%) | called by muse, mutect2, varscan2
- TMCO1 | c.*1223A>G | 3'UTR (SNP) | VAF 44/140 reads (31%) | called by muse, varscan2
- XRRA1 | c.980-41G>A | Intron (SNP) | VAF 122/631 reads (19%) | catalogued as rs934964; called by muse, mutect2, varscan2
